Somatic mutation profile of tumor specimen C3L-10083-01 (aliquot CPT0516780006) from CPTAC case C3L-10083, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.5 years (19,526 days).
Specimen C3L-10083-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f70cf9f-4e72-4b57-8ff6-fc91397b7905.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-10083-31 (Blood Derived Normal), aliquot CPT0516870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3aa405f-3745-485e-9af4-d35e462e0a0c

The open-access MAF lists 146 somatic variants for this specimen: 101 protein-altering or splice-affecting, 40 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 40, Nonsense Mutation 7, Intron 4, Frame Shift Del 3, Splice Site 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 52/399 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- TP53 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 126/528 reads (24%) | hotspot (GDC flag); catalogued as rs1555526097, CM942118, COSV52735517, COSV53025177, COSV53136193, COSV53312374; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.232A>G p.I78V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs373680676; called by muse, mutect2, varscan2
- ACOT12 | c.217A>T p.I73F | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1289980867; called by muse, mutect2, varscan2
- ACOX2 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 43/407 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs138799827; called by muse, varscan2
- ARHGAP15 | c.799A>C p.T267P | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV54511397; called by muse, mutect2, varscan2
- BEGAIN | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62069658; called by mutect2, varscan2
- BROX | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 24/161 reads (15%) | catalogued as rs375053073; called by muse, mutect2, varscan2
- CCDC171 | c.3076C>G p.Q1026E | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV52648996; called by muse, mutect2, varscan2
- CLPSL1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 41/607 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as rs953836231, COSV65814859; called by muse, mutect2
- CPNE1 | c.890G>C p.G297A (on ENST00000352393; = p.G302A on NM_003915.5) | Missense Mutation (SNP) | VAF 56/746 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58291721; called by muse, mutect2
- DGKA | c.31A>T p.S11C | Missense Mutation (SNP) | VAF 65/498 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as rs768940177, COSV100092479, COSV100092486; called by muse, mutect2, varscan2
- DNAH1 | c.6473C>T p.A2158V | Missense Mutation (SNP) | VAF 65/598 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as rs775604295, COSV101326486; called by muse, mutect2, varscan2
- DNAH3 | c.7262G>C p.R2421P | Missense Mutation (SNP) | VAF 67/571 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54547235; called by muse, mutect2, varscan2
- DUSP16 | c.34A>T p.T12S | Missense Mutation (SNP) | VAF 27/205 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.115); catalogued as COSV53807182; called by muse, mutect2, varscan2
- FAM102A | c.470C>T p.S157L (on ENST00000373095 / NM_001035254.3; = p.S15L on NM_203305.2) | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs886683004, COSV55948341; called by muse, mutect2
- FAM135B | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 52/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs775420185, COSV52733676; called by muse, mutect2, varscan2
- FAM178B | c.1375C>G p.L459V | Missense Mutation (SNP) | VAF 72/628 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV59972363; called by muse, mutect2, varscan2
- FAT3 | c.6074A>G p.K2025R | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV53148006, COSV99035557; called by muse, mutect2, varscan2
- GIGYF2 | c.1430del p.S477Mfs*31 | Frame Shift Del (DEL) | VAF 53/243 reads (22%) | catalogued as COSV65251795; called by mutect2, pindel, varscan2
- HS6ST2 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 43/229 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100897306; called by muse, mutect2, varscan2
- IFRD1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.444); catalogued as rs958236876; called by muse, mutect2, varscan2
- INTU | c.2011T>A p.L671M | Missense Mutation (SNP) | VAF 9/213 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.878); catalogued as COSV58875067; called by muse, mutect2
- IQCF2 | c.147G>C p.K49N | Missense Mutation (SNP) | VAF 126/610 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV100290979; called by muse, mutect2, varscan2
- ITPR1 | c.2752+1G>A p.X918_splice (on ENST00000354582; = p.X903_splice on NM_002222.7) | Splice Site (SNP) | VAF 29/122 reads (24%) | catalogued as rs775249713; called by muse, mutect2, varscan2
- KIAA1522 | c.2140C>G p.P714A (on ENST00000373480 / NM_001198972.2; = p.P773A on NM_020888.3) | Missense Mutation (SNP) | VAF 83/480 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1431057402; called by muse, mutect2, varscan2
- MAGEB5 | c.235G>T p.A79S | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as rs772484567; called by muse, mutect2, varscan2
- MORC3 | c.1726G>A p.D576N | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV68687879; called by muse, mutect2, varscan2
- MYBBP1A | c.3890G>A p.R1297Q | Missense Mutation (SNP) | VAF 71/523 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs768330169, COSV54594977; called by muse, mutect2, varscan2
- NCKAP5 | c.2146G>A p.G716R | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs548004146, COSV58455311; called by muse, mutect2
- NECTIN2 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 75/623 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.121); catalogued as rs773746451, COSV99374797; called by muse, mutect2, varscan2
- NID1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 113/575 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs761911797, COSV51620064; called by muse, mutect2, varscan2
- NLRP5 | c.1435G>A p.V479M | Missense Mutation (SNP) | VAF 80/634 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); catalogued as rs374971021, COSV66763712; called by muse, mutect2, varscan2
- NXPE1 | c.775A>G p.T259A (on ENST00000424269; = p.T117A on NM_152315.5) | Missense Mutation (SNP) | VAF 29/394 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV52630114; called by muse, mutect2
- NYX | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 115/589 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs777830978; called by muse, mutect2, varscan2
- OR4A15 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV59034939; called by muse, mutect2, varscan2
- PCDHGA10 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 95/918 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV53948159; called by muse, mutect2, varscan2
- PCDHGB6 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 95/660 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1477022032, COSV53961691; called by muse, mutect2, varscan2
- PLCB1 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV62039802; called by muse, mutect2, varscan2
- PRRT2 | c.163A>C p.T55P | Missense Mutation (SNP) | VAF 82/938 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.221); catalogued as COSV99569399; called by muse, mutect2
- PSMD3 | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 43/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1215381552; called by muse, mutect2, varscan2
- RFLNB | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 55/462 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs782206933, COSV61239599; called by muse, mutect2, varscan2
- RFX4 | c.1111G>A p.D371N (on ENST00000392842 / NM_213594.3; = p.D277N on NM_032491.6) | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV57576431; called by muse, mutect2, varscan2
- SEMA4A | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 50/719 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.269); catalogued as COSV61772398; called by muse, mutect2
- SRGAP3 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs778285286; called by muse, mutect2, varscan2
- SYNE1 | c.16496A>G p.K5499R (on ENST00000367255 / NM_182961.4; = p.K5428R on NM_033071.3) | Missense Mutation (SNP) | VAF 38/288 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV54936582, COSV54962906, COSV99555537; called by muse, mutect2, varscan2
- SYNGR3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 68/577 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV50192442; called by muse, mutect2, varscan2
- TIGD5 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 53/405 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1425133779; called by muse, mutect2, varscan2
- TRAF2 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs200834553, COSV56038604; called by muse, mutect2, varscan2
- TTN | c.18525A>C p.K6175N (on ENST00000591111; = p.K5248N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | PolyPhen benign (0.167); catalogued as COSV100625965; called by muse, mutect2
- TULP4 | c.4480G>A p.A1494T | Missense Mutation (SNP) | VAF 16/526 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as rs1211158748; called by muse, mutect2
- USP14 | c.266T>C p.V89A | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1439274783; called by muse, mutect2, varscan2
- ZNF668 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 74/635 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as rs763070579; called by muse, mutect2, varscan2
- ABCA9 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- ABCC10 | c.1821G>A p.W607* (on ENST00000372530 / NM_001198934.2; = p.W579* on NM_033450.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/1122 reads (5%) | called by muse, mutect2
- ADARB2 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 63/616 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCY7 | c.2613C>A p.Y871* | Nonsense Mutation (SNP) | VAF 32/377 reads (8%) | called by muse, mutect2
- ARSD | c.1722G>C p.Q574H | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- BCL2L14 | c.951_952del p.K317Nfs*7 | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | called by mutect2, pindel, varscan2
- C6orf163 | c.968A>G p.E323G | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- CARS2 | c.1370T>A p.F457Y | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2
- CCDC177 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CDC14B | c.563del p.K188Rfs*29 | Frame Shift Del (DEL) | VAF 23/117 reads (20%) | called by mutect2, pindel, varscan2
- CNNM4 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 71/560 reads (13%) | called by muse, mutect2, varscan2
- DDX24 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 75/603 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC1H1 | c.10516G>T p.D3506Y | Missense Mutation (SNP) | VAF 48/309 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRA1 | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- HEATR1 | c.2654T>A p.V885E | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2
- HHLA1 | c.1457C>G p.T486R | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.226); called by muse, mutect2
- ITCH | c.973C>T p.Q325* (on ENST00000262650 / NM_001257137.3; = p.Q284* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/292 reads (16%) | called by muse, mutect2, varscan2
- KIAA1841 | c.1367G>A p.G456D | Missense Mutation (SNP) | VAF 73/279 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF14 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- KIF2B | c.1383C>G p.S461R | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2
- KMO | c.1436A>T p.Q479L | Missense Mutation (SNP) | VAF 31/262 reads (12%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACROD2 | c.1322C>A p.A441E (on ENST00000642719; = p.A413E on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- MRC1 | c.1781C>A p.P594Q | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC16 | c.33865T>G p.L11289V | Missense Mutation (SNP) | VAF 30/305 reads (10%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MYCBP2 | c.3632A>T p.H1211L (on ENST00000357337; = p.H1249L on NM_015057.5) | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- NCOA6 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 45/416 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NFE2L3 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 96/1124 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- OR2G3 | c.905G>C p.R302T | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OR51E1 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRX | c.3788A>G p.E1263G | Missense Mutation (SNP) | VAF 359/1076 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PTPRS | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 47/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RBM6 | c.3117-2A>T p.X1039_splice | Splice Site (SNP) | VAF 58/457 reads (13%) | called by muse, mutect2, varscan2
- RNF213 | c.7460A>G p.D2487G | Missense Mutation (SNP) | VAF 45/430 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RYR1 | c.13284G>T p.E4428D | Missense Mutation (SNP) | VAF 116/1576 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.011); called by muse, mutect2
- SFTPD | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 102/473 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SGMS1 | c.643T>A p.F215I | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SLC14A2 | c.1905C>T p.D635= | Splice Region (SNP) | VAF 50/266 reads (19%) | called by muse, mutect2, varscan2
- SLC25A10 | c.352A>G p.T118A | Missense Mutation (SNP) | VAF 66/631 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- SLITRK6 | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SORL1 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTBN5 | c.7816G>T p.D2606Y | Missense Mutation (SNP) | VAF 17/495 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SYCP2 | c.3169A>T p.R1057* | Nonsense Mutation (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- TCAF2 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.15); called by muse, mutect2
- TIAM1 | c.2311C>G p.L771V | Missense Mutation (SNP) | VAF 112/720 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMC1 | c.530T>A p.I177N | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- TMEM132D | c.2462A>T p.N821I | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- UGT2B17 | c.1332G>A p.M444I | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- ZBED4 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 64/579 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ALK | c.93C>T p.S31= | Silent (SNP) | VAF 72/706 reads (10%) | called by muse, varscan2
- C2CD3 | c.2658G>A p.K886= | Silent (SNP) | VAF 40/492 reads (8%) | catalogued as rs566441457; called by muse, mutect2
- C2orf16 | c.1173A>T p.T391= | Silent (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- CHPF | c.1023C>T p.A341= | Silent (SNP) | VAF 185/735 reads (25%) | called by muse, mutect2, varscan2
- CNGB1 | c.1881C>T p.C627= | Silent (SNP) | VAF 68/676 reads (10%) | catalogued as rs369525244, COSV51900241; called by muse, mutect2
- CYB5A | c.264C>T p.D88= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- DEFB124 | c.153G>A p.A51= | Silent (SNP) | VAF 70/707 reads (10%) | catalogued as rs143418400, COSV58343127; called by muse, mutect2
- DTX1 | c.774C>G p.L258= | Silent (SNP) | VAF 41/243 reads (17%) | called by muse, mutect2, varscan2
- FRY | c.5568G>A p.Q1856= | Silent (SNP) | VAF 40/361 reads (11%) | catalogued as COSV66567467; called by muse, mutect2, varscan2
- GRTP1 | c.729C>T p.P243= | Silent (SNP) | VAF 48/633 reads (8%) | catalogued as rs370993793; called by muse, mutect2
- HCN1 | c.2640C>T p.D880= | Silent (SNP) | VAF 35/261 reads (13%) | catalogued as rs768551046, COSV57506534; called by muse, mutect2, varscan2
- HSD17B6 | c.651A>C p.T217= | Silent (SNP) | VAF 72/271 reads (27%) | called by muse, mutect2, varscan2
- HSPA4 | c.2484G>A p.S828= | Silent (SNP) | VAF 42/387 reads (11%) | catalogued as rs768573228, COSV100507659; called by muse, mutect2, varscan2
- KCNU1 | c.1035G>A p.V345= | Silent (SNP) | VAF 11/358 reads (3%) | catalogued as COSV67757938; called by muse, mutect2
- KIAA1549 | c.2673C>T p.A891= | Silent (SNP) | VAF 36/827 reads (4%) | called by muse, mutect2
- KRT85 | c.303C>T p.N101= | Silent (SNP) | VAF 102/708 reads (14%) | catalogued as rs745392926, COSV57736025; called by muse, mutect2, varscan2
- MUC6 | c.4428C>T p.N1476= | Silent (SNP) | VAF 160/742 reads (22%) | called by muse, varscan2
- NUDT8 | c.174G>A p.G58= | Silent (SNP) | VAF 76/532 reads (14%) | called by muse, mutect2, varscan2
- NYAP1 | c.2418G>A p.Q806= | Silent (SNP) | VAF 121/947 reads (13%) | called by muse, mutect2, varscan2
- PCDH11X | c.2076C>A p.G692= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV100007501; called by muse, mutect2, varscan2
- PCDH11X | c.2838T>C p.P946= | Silent (SNP) | VAF 73/294 reads (25%) | catalogued as COSV100011443; called by muse, mutect2, varscan2
- PLXNA4 | c.3048G>A p.E1016= | Silent (SNP) | VAF 58/481 reads (12%) | called by muse, mutect2, varscan2
- POTED | c.366C>T p.D122= | Silent (SNP) | VAF 50/1077 reads (5%) | called by muse, mutect2
- POU3F2 | c.51C>A p.S17= | Silent (SNP) | VAF 66/570 reads (12%) | catalogued as COSV100098965; called by muse, varscan2
- PRDM9 | c.1017C>T p.I339= | Silent (SNP) | VAF 48/487 reads (10%) | catalogued as COSV57012040; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 44/368 reads (12%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2, varscan2
- RXRB | c.915G>T p.L305= | Silent (SNP) | VAF 95/796 reads (12%) | called by muse, mutect2, varscan2
- SCN10A | c.1197G>A p.A399= | Silent (SNP) | VAF 50/428 reads (12%) | catalogued as rs759422516; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCRIB | c.1122G>A p.P374= | Silent (SNP) | VAF 66/795 reads (8%) | catalogued as rs1389253524; called by muse, mutect2
- SF1 | c.711T>C p.N237= | Silent (SNP) | VAF 58/399 reads (15%) | called by muse, mutect2, varscan2
- SLC19A1 | c.799C>T p.L267= | Silent (SNP) | VAF 172/809 reads (21%) | catalogued as COSV100229040; called by muse, mutect2, varscan2
- TENM2 | c.5214C>T p.S1738= (on ENST00000518659 / NM_001122679.2; = p.S1499= on NM_001080428.3) | Silent (SNP) | VAF 52/437 reads (12%) | called by muse, mutect2, varscan2
- TMIGD3 | c.483C>T p.A161= (on ENST00000369717 / NM_001081976.2; = p.A242= on NM_020683.7) | Silent (SNP) | VAF 48/410 reads (12%) | called by muse, mutect2, varscan2
- VSX2 | c.903G>T p.L301= | Silent (SNP) | VAF 80/796 reads (10%) | called by muse, mutect2
- WWTR1 | c.420G>A p.R140= | Silent (SNP) | VAF 62/483 reads (13%) | called by muse, mutect2, varscan2
- ZNF415 | c.12C>T p.D4= | Silent (SNP) | VAF 33/305 reads (11%) | catalogued as rs566752458, COSV99701657; called by muse, mutect2, varscan2
- ZNF57 | c.1161G>A p.T387= | Silent (SNP) | VAF 24/304 reads (8%) | catalogued as rs531645223; called by muse, mutect2
- ZNF66 | c.1596T>A p.T532= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- ZNF835 | c.819G>A p.T273= | Silent (SNP) | VAF 81/628 reads (13%) | catalogued as COSV73379357; called by muse, mutect2, varscan2
- ZSWIM6 | c.1530A>G p.P510= | Silent (SNP) | VAF 40/412 reads (10%) | catalogued as COSV53169339; called by muse, mutect2, varscan2
- AC093423.3 | c.138+76052T>A | Intron (SNP) | VAF 54/478 reads (11%) | called by muse, varscan2
- ARHGAP28 | c.2030+1836T>C | Intron (SNP) | VAF 16/236 reads (7%) | catalogued as COSV99148721; called by muse, mutect2
- SLC41A3 | c.1366+74A>G | Intron (SNP) | VAF 54/565 reads (10%) | called by muse, mutect2
- SLCO1C1 | c.1916+24C>G | Intron (SNP) | VAF 13/176 reads (7%) | called by muse, mutect2
- STX3 | c.*38T>C | 3'UTR (SNP) | VAF 50/358 reads (14%) | called by muse, mutect2, varscan2
